Somatic mutation profile of tumor specimen 0DEHNX from CCDI case PBBLSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.3 years (2,296 days).
Specimen 0DEHNX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c330f71-6f7a-4f78-b4f2-c2e0f15981d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHN3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b25d78-fb0f-4114-8331-d69cbe052bb6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD10 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as rs772814750, COSV99949007; called by muse, varscan2
- OR8H3 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 264/574 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100538699; called by muse, varscan2
